Gene-level copy-number profile of tumor specimen TCGA-37-4130-01A from TCGA case TCGA-37-4130, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 56.5 years (20,652 days).
Specimen TCGA-37-4130-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e22b53a6-d00d-4801-94e9-38e59cebc053.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-4130-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 845 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c7c0aa87-68c0-48d3-8d7e-62f3212f343f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 190; copy number 2: 1,291; copy number 3: 15,544; copy number 4: 16,406; copy number 5: 11,032; copy number 6: 8,169; copy number 7: 3,531; copy number 8: 1,857; copy number 9: 867; copy number 10: 183; copy number 11: 575; copy number 12: 55; copy number 19: 78.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-4130-01A-01D-1969-01): tumor purity 0.4, ploidy 4.62, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,758 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:236,567,787–242,160,153, 146 genes, copy number 9 (broad region; genes not listed).
- chr4:35,487,812–70,367,158, 513 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr5:58,198–9,712,378, 196 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:66,363,774–71,815,625, 88 genes, copy number 9–11 (broad region; genes not listed).
- chr8:71,841,549–71,896,330, 2 genes, copy number 9: MSC, RPS20P20.
- chr8:73,008,856–82,961,926, 159 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:24,679,547–25,452,628, 24 genes, copy number 10 (within-gene range 5–10): AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1.
- chr20:41,547,422–64,313,132, 575 genes, copy number 9–19 (broad region; genes not listed).
- chr21:45,073,853–46,665,124, 55 genes, copy number 12 (within-gene range 4–12): ADARB1, AL133499.1, LINC00334, POFUT2, LINC00205, BX322557.2, LINC00315, BX322557.1, LINC00316, MTCO1P3, BX322559.1, BX322562.1, COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815, SLC19A1, LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 190. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
